Somatic mutation profile of tumor specimen CDDP-ABJO-TTP1-G (aliquot CDDP-ABJO-TTP1-G-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABJO, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54 years.
Specimen CDDP-ABJO-TTP1-G: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec50a216-cd97-4905-813e-ec29a1441325.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABJO-NB1-A (Blood Derived Normal), aliquot CDDP-ABJO-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6fc7183-7dd4-41ae-8cc8-5b45fc68bb77

The open-access MAF lists 231 somatic variants for this specimen: 151 protein-altering or splice-affecting, 45 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 45, Intron 18, Frame Shift Del 12, RNA 8, Splice Site 5, Nonsense Mutation 5, 5'UTR 4, Splice Region 3, 3'Flank 2, 5'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3728G>T p.R1243L | Missense Mutation (SNP) | VAF 203/626 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100757983, COSV60796547, COSV60801666; called by muse, mutect2, varscan2
- AASDH | c.2673G>T p.K891N | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52705871; called by muse, mutect2, varscan2
- ADAMTS8 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as rs757237747; called by muse, mutect2, varscan2
- ADGRA1 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs930006726; called by muse, mutect2, varscan2
- ASB9 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100995549; called by muse, mutect2, varscan2
- BCHE | c.1770C>G p.N590K | Missense Mutation (SNP) | VAF 70/340 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.305); catalogued as COSV52259851, COSV52262240; called by muse, mutect2, varscan2
- C8orf33 | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 75/282 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV58895529; called by muse, mutect2, varscan2
- CDO1 | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 60/283 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs757126802; called by muse, mutect2, varscan2
- CORO6 | c.1241G>T p.R414L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs558798899; called by muse, mutect2, varscan2
- CSPG4 | c.5188G>T p.A1730S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV57898306; called by muse, mutect2
- CTTN | c.1616G>T p.G539V | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764143657, COSV57232747; called by muse, mutect2, varscan2
- CYLD | c.2084G>T p.R695M | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100282428; called by muse, mutect2, varscan2
- DENND1A | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs376233242; called by muse, mutect2, varscan2
- DNAH14 | c.5026G>A p.G1676R (on ENST00000445597; = p.G2081R on NM_001367479.1) | Missense Mutation (SNP) | VAF 87/575 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1018983241, COSV70532417; called by muse, mutect2, varscan2
- DYRK1B | c.1177del p.E393Sfs*110 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs1270847383; called by mutect2, pindel, varscan2
- EIF4E1B | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV53779855; called by muse, mutect2, varscan2
- ERBB2 | c.1003A>T p.S335C | Missense Mutation (SNP) | VAF 103/379 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV54074253; called by muse, mutect2, varscan2
- FAT4 | c.6106C>G p.Q2036E | Missense Mutation (SNP) | VAF 69/311 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV58689259; called by muse, mutect2, varscan2
- FNDC1 | c.1870G>C p.A624P | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV51934607; called by muse, mutect2, varscan2
- GSG1L | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1415501560; called by muse, mutect2
- GTF2E1 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs200375471; called by muse, mutect2, varscan2
- HYDIN | c.6400A>T p.T2134S | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.058); catalogued as COSV59250924; called by muse, mutect2, varscan2
- ITGA10 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 287/545 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs148231059; called by muse, mutect2, varscan2
- ITIH5 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 45/200 reads (23%) | catalogued as COSV53668734, COSV99905350; called by muse, mutect2, varscan2
- KCNK12 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.087); catalogued as rs773257874; called by muse, mutect2, varscan2
- KCNMA1 | c.2336C>T p.P779L (on ENST00000286628 / NM_001161352.2; = p.P721L on NM_002247.4) | Missense Mutation (SNP) | VAF 128/492 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1480996634; called by muse, mutect2, varscan2
- KCP | c.3031C>T p.P1011S (on ENST00000620378; = p.P1071S on NM_001366122.1) | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as rs568065421; called by muse, mutect2, varscan2
- KEAP1 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 154/509 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV50260624; called by muse, mutect2, varscan2
- KIF1A | c.2656G>C p.A886P | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100241993; called by muse, mutect2, varscan2
- LRRIQ1 | c.4756G>A p.E1586K | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs1486232667; called by muse, mutect2, varscan2
- NLRP13 | c.2804C>G p.S935C | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs369393061; called by muse, mutect2, varscan2
- NLRP5 | c.3227C>A p.A1076D | Missense Mutation (SNP) | VAF 63/452 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.086); catalogued as rs749480325; called by muse, mutect2, varscan2
- PCDHA7 | c.2183C>A p.S728Y | Missense Mutation (SNP) | VAF 93/371 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); catalogued as COSV100970460; called by muse, mutect2, varscan2
- PCDHGA3 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV53895175, COSV53932691, COSV99542394; called by muse, mutect2, varscan2
- PCLO | c.12137A>T p.Y4046F | Missense Mutation (SNP) | VAF 113/436 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV100435218; called by muse, mutect2, varscan2
- PCSK1 | c.1468C>A p.P490T | Missense Mutation (SNP) | VAF 113/428 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV60735676; called by muse, mutect2, varscan2
- PRKD3 | c.1349A>G p.N450S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as rs542117212; called by muse, mutect2, varscan2
- RHAG | c.416C>A p.T139N | Missense Mutation (SNP) | VAF 139/607 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs778091087; called by muse, mutect2, varscan2
- RUNX1T1 | c.608C>A p.A203D (on ENST00000265814 / NM_001198628.1; = p.A176D on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV99753445; called by muse, mutect2, varscan2
- SALL1 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 181/805 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV51753714; called by muse, mutect2, varscan2
- SEC24B | c.3293G>A p.R1098H | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776160052; called by muse, mutect2, varscan2
- SEMA3D | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.019); catalogued as COSV52386572; called by muse, mutect2, varscan2
- SERINC3 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs765692682; called by muse, mutect2, varscan2
- SERPINE3 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 67/378 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV60878862; called by muse, mutect2, varscan2
- SMARCD1 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs141728974, COSV67411901; called by muse, mutect2, varscan2
- SPTBN5 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as rs542811447; called by muse, mutect2, varscan2
- STAG2 | c.2925-1G>C p.X975_splice | Splice Site (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99495388; called by muse, mutect2
- SUMF1 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 112/530 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768700845, COSV55995448; called by muse, varscan2
- TMEM129 | c.583C>G p.R195G | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as COSV57558722; called by muse, mutect2, varscan2
- TNRC6A | c.919G>T p.G307* | Nonsense Mutation (SNP) | VAF 35/181 reads (19%) | catalogued as rs1447885309; called by muse, mutect2, varscan2
- TNRC6A | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs1247691090; called by muse, mutect2, varscan2
- TRIM48 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 146/773 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70161554; called by muse, mutect2, varscan2
- TRPA1 | c.1297C>A p.L433I | Missense Mutation (SNP) | VAF 137/709 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs1443478456; called by muse, mutect2, varscan2
- VWA3A | c.1444C>T p.L482F | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1344998681; called by muse, mutect2, varscan2
- XKR5 | c.5A>T p.H2L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs548437072; called by mutect2, varscan2
- ZNF148 | c.499del p.T167Pfs*68 | Frame Shift Del (DEL) | VAF 44/218 reads (20%) | catalogued as COSV100641909; called by mutect2, pindel, varscan2
- ZNF781 | c.434C>G p.T145R | Missense Mutation (SNP) | VAF 59/446 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.077); catalogued as COSV62201903; called by muse, mutect2, varscan2
- ZZEF1 | c.7115G>A p.R2372H | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs375499242; called by muse, mutect2, varscan2
- ABI1 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 15/393 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADAM22 | c.2111G>C p.R704T | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRF5 | c.2792A>G p.N931S | Missense Mutation (SNP) | VAF 13/374 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- ADRB3 | c.103T>A p.W35R | Missense Mutation (SNP) | VAF 71/371 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASAH2 | c.903del p.I302Sfs*6 | Frame Shift Del (DEL) | VAF 138/745 reads (19%) | called by mutect2, pindel, varscan2
- B2M | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 102/526 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BCAT1 | c.132del p.N45Ifs*14 | Frame Shift Del (DEL) | VAF 70/341 reads (21%) | called by mutect2, pindel, varscan2
- BDP1 | c.2373-4_2374delinsTTTTTT p.X791_splice | Splice Site (ONP) | VAF 8/60 reads (13%) | called by mutect2*, pindel
- CALCB | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 83/359 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAMSAP3 | c.2212C>G p.P738A | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CAP2 | c.434G>T p.W145L | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- CAV3 | c.297C>A p.H99Q | Missense Mutation (SNP) | VAF 96/436 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CDRT15L2 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- CEMIP2 | c.2182G>T p.G728C | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CHMP4C | c.524A>C p.E175A | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CHPF | c.1325G>T p.R442L | Missense Mutation (SNP) | VAF 75/353 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CHRNA7 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by mutect2, varscan2
- CLEC12B | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 43/232 reads (19%) | called by muse, mutect2, varscan2
- CLTCL1 | c.2779G>T p.D927Y | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNGA3 | c.1284G>C p.K428N | Missense Mutation (SNP) | VAF 216/981 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- COL6A6 | c.6314C>A p.S2105Y | Missense Mutation (SNP) | VAF 74/308 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSF2RB | c.2343G>T p.R781S | Missense Mutation (SNP) | VAF 106/444 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD1 | c.5069G>T p.R1690I (on ENST00000520002; = p.R1689I on NM_033225.6) | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTC1 | c.3128G>C p.C1043S | Missense Mutation (SNP) | VAF 78/245 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DMXL1 | c.4912G>C p.D1638H | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSPP | c.764A>G p.E255G | Missense Mutation (SNP) | VAF 42/676 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- ERBB2 | c.3370A>T p.T1124S | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EXD2 | c.1647C>A p.T549= (on ENST00000312994 / NM_001193362.1; = p.T424= on NM_018199.3) | Splice Region (SNP) | VAF 24/106 reads (23%) | called by muse, varscan2
- EYS | c.2014G>T p.G672* | Nonsense Mutation (SNP) | VAF 101/381 reads (27%) | called by muse, mutect2, varscan2
- FAM120B | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FAM47E-STBD1 | c.209del p.P70Lfs*53 | Frame Shift Del (DEL) | VAF 107/580 reads (18%) | called by mutect2, pindel, varscan2
- GGA2 | c.1349C>G p.S450C | Missense Mutation (SNP) | VAF 82/350 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- GHSR | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 28/748 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GPR158 | c.1535C>A p.S512* | Nonsense Mutation (SNP) | VAF 106/383 reads (28%) | called by muse, mutect2, varscan2
- HAND2 | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCN1 | c.63C>A p.F21L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, varscan2
- HMG20A | c.584A>G p.D195G | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNA2 | c.1069del p.Q357Sfs*16 | Frame Shift Del (DEL) | VAF 50/307 reads (16%) | called by mutect2, pindel, varscan2
- KCNT2 | c.1469A>T p.Y490F | Missense Mutation (SNP) | VAF 84/238 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- KLHL25 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- LEPR | c.2026G>T p.V676F | Missense Mutation (SNP) | VAF 117/545 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAP3K9 | c.2974C>G p.L992V (on ENST00000554752 / NM_001284230.1; = p.L1006V on NM_033141.4) | Missense Mutation (SNP) | VAF 102/535 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MARF1 | c.2845G>T p.G949W | Missense Mutation (SNP) | VAF 136/614 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCM8 | c.1543dup p.C515Lfs*5 | Frame Shift Ins (INS) | VAF 75/337 reads (22%) | called by mutect2, pindel, varscan2
- MINDY4B | c.1228C>A p.R410S | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MYH2 | c.2063-5T>C | Splice Region (SNP) | VAF 192/1019 reads (19%) | called by muse, mutect2, varscan2
- NDOR1 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- NETO1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2
- NPHS1 | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 135/1213 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OR6V1 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 92/611 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2
- OR9Q1 | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PCDHB2 | c.1612C>A p.R538S | Missense Mutation (SNP) | VAF 192/891 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PDXK | c.643G>T p.V215L | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PHACTR3 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 64/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLG | c.831G>T p.K277N | Missense Mutation (SNP) | VAF 117/593 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PPFIA3 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RGS3 | c.2161G>C p.D721H (on ENST00000350696 / NM_001282923.2; = p.D440H on NM_130795.4) | Missense Mutation (SNP) | VAF 110/515 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- RHAG | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 132/578 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHBDL3 | c.1134_1138del p.T379Lfs*83 | Frame Shift Del (DEL) | VAF 112/787 reads (14%) | called by mutect2, pindel, varscan2
- RNF150 | c.1042G>C p.G348R | Missense Mutation (SNP) | VAF 124/550 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SALL3 | c.1105A>T p.S369C | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- SASH3 | c.451C>A p.L151I | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, varscan2
- SCN3A | c.3218G>T p.G1073V | Missense Mutation (SNP) | VAF 121/582 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SENP6 | c.2002_2003del p.V668Yfs*3 | Frame Shift Del (DEL) | VAF 74/381 reads (19%) | called by mutect2, pindel, varscan2
- SETX | c.6525C>A p.F2175L | Missense Mutation (SNP) | VAF 99/542 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SHANK2 | c.3943A>T p.M1315L | Missense Mutation (SNP) | VAF 212/1007 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- SLC11A1 | c.1471C>A p.L491M | Missense Mutation (SNP) | VAF 80/378 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- SLC25A31 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 66/268 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, varscan2
- SLC4A4 | c.2344del p.A783Lfs*12 (on ENST00000264485 / NM_001098484.3; = p.A739Lfs*12 on NM_003759.4) | Frame Shift Del (DEL) | VAF 170/688 reads (25%) | called by mutect2, pindel, varscan2
- SMG1 | c.5138C>T p.S1713L | Missense Mutation (SNP) | VAF 74/455 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPATC1 | c.1372C>A p.L458M | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPOCK3 | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 60/274 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- TENT2 | c.596del p.L199Wfs*6 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- TFPI | c.122-1G>T p.X41_splice | Splice Site (SNP) | VAF 76/299 reads (25%) | called by muse, mutect2, varscan2
- TLE3 | c.1978del p.S660Pfs*57 | Frame Shift Del (DEL) | VAF 34/165 reads (21%) | called by mutect2, pindel, varscan2
- TMEM126A | c.87-3C>A | Splice Region (SNP) | VAF 83/451 reads (18%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.522-2A>T p.X174_splice | Splice Site (SNP) | VAF 152/664 reads (23%) | called by muse, mutect2, varscan2
- TRIM48 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 145/774 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM6 | c.1909A>C p.K637Q | Missense Mutation (SNP) | VAF 52/599 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TSR1 | c.1686_1693del p.S563Pfs*23 | Frame Shift Del (DEL) | VAF 44/264 reads (17%) | called by mutect2, pindel, varscan2
- U2AF2 | c.945+1G>C p.X315_splice | Splice Site (SNP) | VAF 143/220 reads (65%) | called by muse, mutect2, varscan2
- UGGT1 | c.1428T>G p.S476R | Missense Mutation (SNP) | VAF 70/377 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ULK3 | c.879G>C p.K293N | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2
- UNC80 | c.8458G>A p.V2820M | Missense Mutation (SNP) | VAF 69/354 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP9Y | c.5059G>T p.D1687Y | Missense Mutation (SNP) | VAF 160/349 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VILL | c.1528C>T p.L510F | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, varscan2
- VPS13D | c.6791G>T p.R2264L | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- VWA3A | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- WDR87 | c.6557A>T p.E2186V | Missense Mutation (SNP) | VAF 47/429 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); called by muse, varscan2
- XPOT | c.2562A>T p.E854D | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- XYLT1 | c.1837G>T p.D613Y | Missense Mutation (SNP) | VAF 118/521 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF572 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACACB | c.5940G>T p.L1980= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV58148007; called by muse, mutect2, varscan2
- ADD2 | c.627C>T p.F209= | Silent (SNP) | VAF 28/188 reads (15%) | called by muse, mutect2, varscan2
- AGRN | c.5502G>A p.P1834= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs371302168; called by muse, mutect2, varscan2
- ALDH8A1 | c.1278C>T p.S426= | Silent (SNP) | VAF 122/559 reads (22%) | called by muse, mutect2, varscan2
- ANKRD30B | c.1851G>T p.L617= | Silent (SNP) | VAF 42/253 reads (17%) | called by muse, mutect2, varscan2
- ATOH1 | c.591A>G p.K197= | Silent (SNP) | VAF 95/426 reads (22%) | catalogued as rs773761668, COSV60038135; called by muse, mutect2, varscan2
- BARHL2 | c.1060C>A p.R354= | Silent (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2, varscan2
- C1orf116 | c.1278A>T p.P426= | Silent (SNP) | VAF 105/697 reads (15%) | called by muse, mutect2, varscan2
- C5 | c.2184C>T p.F728= | Silent (SNP) | VAF 51/268 reads (19%) | called by muse, mutect2, varscan2
- CCDC168 | c.5115C>A p.P1705= | Silent (SNP) | VAF 94/398 reads (24%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.1944G>C p.T648= | Silent (SNP) | VAF 145/682 reads (21%) | catalogued as COSV62141320; called by muse, mutect2, varscan2
- COL6A6 | c.6315C>A p.S2105= | Silent (SNP) | VAF 75/310 reads (24%) | called by muse, mutect2, varscan2
- COL9A3 | c.123G>A p.G41= | Silent (SNP) | VAF 21/96 reads (22%) | called by muse, mutect2, varscan2
- DGKA | c.765C>T p.V255= | Silent (SNP) | VAF 76/342 reads (22%) | catalogued as COSV59386145; called by muse, mutect2, varscan2
- DQX1 | c.576A>G p.E192= | Silent (SNP) | VAF 102/492 reads (21%) | catalogued as rs1449994468; called by muse, mutect2, varscan2
- DRD2 | c.192G>A p.A64= | Silent (SNP) | VAF 108/415 reads (26%) | catalogued as rs1435479808, COSV60756453; called by muse, mutect2, varscan2
- EFHC2 | c.1014G>T p.L338= | Silent (SNP) | VAF 86/180 reads (48%) | called by muse, mutect2, varscan2
- FAM110A | c.853A>C p.R285= | Silent (SNP) | VAF 90/375 reads (24%) | called by muse, mutect2, varscan2
- FOS | c.837G>A p.R279= | Silent (SNP) | VAF 260/1097 reads (24%) | catalogued as rs1201864399; called by muse, mutect2, varscan2
- GABRA5 | c.567G>C p.L189= | Silent (SNP) | VAF 97/562 reads (17%) | called by muse, mutect2, varscan2
- GPR35 | c.561G>T p.V187= | Silent (SNP) | VAF 82/261 reads (31%) | called by muse, mutect2, varscan2
- INSM1 | c.1029C>A p.P343= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1471937707; called by mutect2, varscan2
- KCNA5 | c.864C>A p.P288= | Silent (SNP) | VAF 79/318 reads (25%) | called by muse, mutect2, varscan2
- LRIT2 | c.171C>T p.F57= | Silent (SNP) | VAF 30/177 reads (17%) | called by muse, mutect2, varscan2
- MAML1 | c.546G>T p.G182= | Silent (SNP) | VAF 38/219 reads (17%) | catalogued as rs775726916; called by muse, mutect2, varscan2
- MAML1 | c.547C>T p.L183= | Silent (SNP) | VAF 37/219 reads (17%) | catalogued as rs760897990; called by muse, mutect2, varscan2
- MAST4 | c.2424A>G p.A808= (on ENST00000403625 / NM_001164664.2; = p.A619= on NM_015183.3) | Silent (SNP) | VAF 63/430 reads (15%) | called by muse, mutect2, varscan2
- NMT2 | c.1200G>C p.L400= | Silent (SNP) | VAF 42/339 reads (12%) | called by muse, mutect2, varscan2
- NPAP1 | c.915G>A p.E305= | Silent (SNP) | VAF 15/162 reads (9%) | catalogued as rs140625833; called by muse, mutect2
- NWD2 | c.4311C>T p.T1437= | Silent (SNP) | VAF 91/354 reads (26%) | called by muse, mutect2, varscan2
- OR4F17 | c.366C>A p.P122= | Silent (SNP) | VAF 14/130 reads (11%) | called by mutect2, varscan2
- PCDHB2 | c.1779G>A p.A593= | Silent (SNP) | VAF 88/604 reads (15%) | catalogued as rs1554271559; called by muse, mutect2, varscan2
- PLEKHG4B | c.390C>T p.P130= (on ENST00000283426; = p.P486= on NM_052909.5) | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs201743310, COSV52046044; called by mutect2, varscan2
- RBFOX3 | c.201C>A p.I67= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV101332268; called by muse, mutect2, varscan2
- RNASE3 | c.87C>T p.P29= | Silent (SNP) | VAF 161/628 reads (26%) | called by muse, mutect2, varscan2
- RPL5 | c.690C>T p.S230= | Silent (SNP) | VAF 69/325 reads (21%) | catalogued as rs766117227; called by muse, mutect2, varscan2
- RYR3 | c.10371C>T p.V3457= (on ENST00000389232; = p.V3458= on NM_001036.6) | Silent (SNP) | VAF 34/243 reads (14%) | catalogued as COSV66808601; called by muse, mutect2, varscan2
- SLITRK4 | c.72G>T p.V24= | Silent (SNP) | VAF 42/91 reads (46%) | called by muse, mutect2, varscan2
- SPATC1 | c.1371C>A p.I457= | Silent (SNP) | VAF 49/255 reads (19%) | called by muse, mutect2, varscan2
- TAS2R38 | c.381C>A p.T127= | Silent (SNP) | VAF 80/326 reads (25%) | catalogued as COSV101516396, COSV101516534; called by muse, mutect2, varscan2
- TMEM120B | c.741G>C p.L247= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as rs375094675; called by muse, mutect2, varscan2
- TRIM46 | c.876C>T p.I292= | Silent (SNP) | VAF 65/490 reads (13%) | called by muse, mutect2, varscan2
- TSC22D2 | c.1704A>G p.A568= | Silent (SNP) | VAF 16/383 reads (4%) | catalogued as rs1310678313; called by muse, mutect2
- VPS13D | c.6792G>T p.R2264= | Silent (SNP) | VAF 38/169 reads (22%) | catalogued as COSV99169622; called by muse, mutect2, varscan2
- VWF | c.6483C>T p.A2161= | Silent (SNP) | VAF 143/565 reads (25%) | called by muse, mutect2, varscan2
- AC002519.1 | chr16:31793741 G>T | 3'Flank (SNP) | VAF 55/220 reads (25%) | called by muse, mutect2, varscan2
- AC009039.2 | chr16:52084423 C>T | 5'Flank (SNP) | VAF 88/457 reads (19%) | called by muse, mutect2
- ANKRD26P1 | n.103A>G | RNA (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- ASAP1 | c.186+17154G>T | Intron (SNP) | VAF 51/268 reads (19%) | called by muse, mutect2, varscan2
- BAALC | c.161-17217T>A | Intron (SNP) | VAF 87/347 reads (25%) | called by muse, mutect2, varscan2
- CACNA1I | c.6027+13C>A | Intron (SNP) | VAF 75/348 reads (22%) | called by muse, mutect2, varscan2
- CATSPER2 | c.-87+33G>A | Intron (SNP) | VAF 17/123 reads (14%) | catalogued as rs1445935205; called by muse, mutect2, varscan2
- CCDC144CP | n.2161del | RNA (DEL) | VAF 59/422 reads (14%) | called by mutect2, pindel, varscan2
- CCDC18 | c.-3+252C>G | Intron (SNP) | VAF 9/57 reads (16%) | catalogued as rs1342851809; called by muse, mutect2, varscan2
- CDH8 | c.1537-19G>T | Intron (SNP) | VAF 88/367 reads (24%) | called by muse, mutect2, varscan2
- FAM197Y1 | n.73A>C | RNA (SNP) | VAF 156/357 reads (44%) | called by muse, mutect2, varscan2
- FAM90A27P | n.66C>A | RNA (SNP) | VAF 39/205 reads (19%) | called by muse, mutect2, varscan2
- FAM90A27P | n.738G>A | RNA (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2, varscan2
- FMN1 | c.3508-62A>T | Intron (SNP) | VAF 82/319 reads (26%) | called by muse, mutect2, varscan2
- GC | c.-27G>C | 5'UTR (SNP) | VAF 68/275 reads (25%) | called by muse, varscan2
- GDNF | c.*6G>A | 3'UTR (SNP) | VAF 66/372 reads (18%) | called by muse, mutect2, varscan2
- HESX1 | c.-1G>C | 5'UTR (SNP) | VAF 144/648 reads (22%) | called by muse, mutect2, varscan2
- HSPA7 | n.963G>A | RNA (SNP) | VAF 113/904 reads (13%) | called by muse, mutect2, varscan2
- IGLV7-43 | c.-17C>A | 5'UTR (SNP) | VAF 93/364 reads (26%) | called by muse, mutect2, varscan2
- JAZF1-AS1 | n.923G>T | RNA (SNP) | VAF 78/343 reads (23%) | called by muse, mutect2, varscan2
- LTBP4 | c.451+1300G>A | Intron (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- MIR138-1 | n.41G>T | RNA (SNP) | VAF 90/394 reads (23%) | called by muse, mutect2, varscan2
- MIR6080 | chr17:64780048 C>T | 5'Flank (SNP) | VAF 97/519 reads (19%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92598A>G | Intron (SNP) | VAF 70/341 reads (21%) | called by muse, mutect2, varscan2
- MPRIP | c.2164-5033G>C | Intron (SNP) | VAF 26/407 reads (6%) | catalogued as rs981001742; called by muse, mutect2
- PDZD7 | c.-90G>A | 5'UTR (SNP) | VAF 86/377 reads (23%) | catalogued as rs1361078735, COSV99827553; called by muse, mutect2, varscan2
- RASGRP2 | c.-71-13T>A | Intron (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- RIOK2 | c.205+48C>T | Intron (SNP) | VAF 79/376 reads (21%) | called by muse, mutect2, varscan2
- SMARCA4 | c.3547-21G>T | Intron (SNP) | VAF 175/508 reads (34%) | called by muse, mutect2, varscan2
- UROS | c.394+4434G>T | Intron (SNP) | VAF 55/255 reads (22%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25071604 G>A | 3'Flank (SNP) | VAF 178/800 reads (22%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-2875A>G | Intron (SNP) | VAF 64/284 reads (23%) | called by muse, mutect2, varscan2
- YWHAZ | c.294+468A>G | Intron (SNP) | VAF 35/222 reads (16%) | called by muse, mutect2, varscan2
- ZNF606 | c.-52+413C>T | Intron (SNP) | VAF 61/542 reads (11%) | catalogued as COSV100008550; called by muse, mutect2, varscan2
- ZSWIM2 | c.165+56C>A | Intron (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
